CCDI case PBCHNC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0a537c4f-b167-41af-8f64-4a43c4e301a4

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,033 days).

Biospecimens (3 samples)
- Sample 0DS6KR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS6L6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS6LK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
